Somatic mutation profile of tumor specimen TCGA-EY-A1GL-01A (aliquot TCGA-EY-A1GL-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.4 years (18,761 days).
Specimen TCGA-EY-A1GL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da79fad0-108c-4413-a00f-bbf684312a51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GL-10A (Blood Derived Normal), aliquot TCGA-EY-A1GL-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cfe8872-1144-4419-a715-fdbdc9860e56

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 2, Nonstop Mutation 1, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- DYRK1A | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as rs780441716, COSV58295398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 23/26 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 66/88 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMCX6 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs782087344, COSV100726238; called by muse, mutect2, varscan2
- ASCC2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100316336; called by muse, mutect2, varscan2
- CANT1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753107695, COSV100185315; called by muse, mutect2, varscan2
- CLCA2 | c.1765C>G p.L589V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV100991599; called by muse, mutect2, varscan2
- CMC4 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV62898628; called by muse, mutect2, varscan2
- CYFIP2 | c.1803G>T p.K601N (on ENST00000616178 / NM_001291722.2; = p.K576N on NM_014376.4) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100557218; called by muse, mutect2, varscan2
- CYP2A13 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100386887; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DOCK4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs371441977; called by muse, mutect2, varscan2
- DOP1B | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs370749068, COSV101215564; called by mutect2, varscan2
- EDA | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as CM011769, COSV100140917, COSV100140970; called by muse, mutect2, varscan2
- FMNL3 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.992); catalogued as rs749829489, COSV99526573; called by muse, mutect2, varscan2
- LCE2B | c.333A>G p.*111Wext*70 | Nonstop Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100909320; called by muse, mutect2, varscan2
- LRSAM1 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs747368361, COSV100031665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K15 | c.2444A>G p.Y815C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349031504, COSV100135050; called by muse, mutect2, varscan2
- MAST2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs959178314, COSV63617422; called by muse, mutect2, varscan2
- MPV17L | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1445631252, COSV99806241; called by muse, mutect2
- NDNF | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV101113199; called by muse, mutect2, varscan2
- PACS2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1463502972, COSV100330845; called by muse, mutect2, varscan2
- PCDH9 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs148716657; called by muse, mutect2, varscan2
- PCDHB4 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99522319; called by muse, mutect2, varscan2
- PDE4D | c.482C>T p.A161V (on ENST00000340635 / NM_001104631.2; = p.A25V on NM_006203.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs562952667, COSV100507492; called by muse, mutect2, varscan2
- RAD23A | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100330840; called by muse, mutect2, varscan2
- SIGIRR | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755790244, COSV100230144; called by mutect2, varscan2
- SPOP | c.240C>G p.S80R | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61652615; called by muse, mutect2, varscan2
- TMEM18 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201376241; called by muse, mutect2, varscan2
- TSNAXIP1 | c.254T>A p.I85K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99535209; called by muse, mutect2, varscan2
- TULP4 | c.659C>G p.P220R | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893609, COSV100893877, COSV100893888; called by muse, mutect2, varscan2
- ZC3H4 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99452486; called by muse, mutect2, varscan2
- DAP | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- JARID2 | c.2395_2398del p.E799Rfs*23 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by pindel, varscan2
- MRC1 | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NXPE4 | c.1527dup p.I510Yfs*3 (on ENST00000375478 / NM_001077639.2; = p.I226Yfs*3 on NM_017678.3) | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- ANAPC5 | c.75C>T p.G25= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99946308; called by muse, mutect2, varscan2
- CCN4 | c.510G>A p.P170= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs775016662, COSV51530348; called by muse, mutect2, varscan2
- CDK9 | c.876C>T p.I292= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs574082027, COSV64723783; called by muse, mutect2, varscan2
- CELSR1 | c.6588C>T p.A2196= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99418879; called by muse, varscan2
- CRTAP | c.945C>T p.A315= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs1011445335, COSV100310137; called by muse, mutect2, varscan2
- GABRB3 | c.321G>A p.T107= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs367761610; called by muse, mutect2, varscan2
- KLHL21 | c.1614C>T p.R538= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1299268104, COSV100887264; called by muse, mutect2, varscan2
- NEB | c.2793C>T p.I931= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99424852; called by muse, mutect2, varscan2
- PCDHA7 | c.1686G>A p.A562= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as COSV65341598; called by muse, mutect2, varscan2
- SIGLEC6 | c.834C>A p.G278= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV58432667; called by muse, mutect2, varscan2
- SLA2 | c.123C>A p.G41= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99481460; called by muse, mutect2, varscan2
- SOX7 | c.246G>A p.S82= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs769113063, COSV58730973; called by muse, mutect2, varscan2
- TAAR8 | c.555C>T p.C185= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs142407090; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500962 G>A | 5'Flank (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
